Somatic mutation profile of tumor specimen TCGA-BT-A42E-01A (aliquot TCGA-BT-A42E-01A-11D-A23U-08) from TCGA case TCGA-BT-A42E, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.0 years (27,045 days).
Specimen TCGA-BT-A42E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a801c9f6-4b72-43c8-8638-41c24a06edbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A42E-10A (Blood Derived Normal), aliquot TCGA-BT-A42E-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cc09fa0-98b9-4048-b633-ee4837cf7c11

The open-access MAF lists 189 somatic variants for this specimen: 147 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 41, Nonsense Mutation 12, Frame Shift Ins 1, Intron 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4906C>T p.Q1636* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs1060501627, COSV53739171, COSV53754554; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV61787442; called by muse, mutect2, varscan2
- ABCC11 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs983737712, COSV62324123; called by muse, mutect2, varscan2
- ACADVL | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV50036863; called by muse, mutect2, varscan2
- ACSS3 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs751989029, COSV54094570; called by muse, mutect2, varscan2
- ADAMTS14 | c.1684G>C p.G562R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64603559; called by muse, varscan2
- ADAMTSL1 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs747836852, COSV65888191; called by muse, mutect2, varscan2
- ADAMTSL2 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63203151; called by muse, mutect2, varscan2
- ADGRL4 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV66062536; called by muse, mutect2, varscan2
- AHNAK2 | c.8021C>G p.S2674C | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60919686; called by muse, mutect2, varscan2
- AMIGO2 | c.1264T>C p.C422R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56974691; called by muse, mutect2, varscan2
- ANKRD27 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60128968, COSV60133068; called by muse, mutect2, varscan2
- ARHGEF40 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53881526; called by muse, mutect2
- ASB8 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV56658549; called by muse, mutect2, varscan2
- AUP1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as rs1345091927, COSV57817782; called by muse, mutect2, varscan2
- BAHD1 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69084194; called by muse, mutect2, varscan2
- BEND2 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV66216251; called by muse, mutect2, varscan2
- BICRA | c.2675C>G p.S892C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV67605258; called by muse, mutect2, varscan2
- BRIP1 | c.3167C>G p.S1056* | Nonsense Mutation (SNP) | VAF 49/160 reads (31%) | catalogued as COSV99369651; called by muse, mutect2, varscan2
- C19orf18 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV58706718; called by muse, mutect2, varscan2
- CAB39 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1196616191, COSV51477549; called by muse, mutect2, varscan2
- CACNA1G | c.5192C>T p.A1731V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369515451; called by muse, mutect2, varscan2
- CACTIN | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs376455756; called by muse, mutect2, varscan2
- CASP4 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67744560; called by muse, mutect2
- CCDC88A | c.4952G>C p.R1651T (on ENST00000436346 / NM_001365480.1; = p.R1623T on NM_018084.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as rs1197226051, COSV55064444; called by muse, mutect2, varscan2
- CEACAM3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as rs782329916, COSV55761056; called by muse, mutect2, varscan2
- CLBA1 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66348185; called by muse, mutect2, varscan2
- CLCA4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55369196; called by muse, mutect2, varscan2
- CLN3 | c.1216C>G p.L406V (on ENST00000360019 / NM_001286104.2; = p.L430V on NM_000086.2) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV61106362; called by muse, mutect2, varscan2
- COLGALT2 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs910803982, COSV62299068; called by muse, mutect2, varscan2
- COQ5 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs754531913, COSV99942222; called by muse, mutect2, varscan2
- CPD | c.2736G>C p.E912D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.4); catalogued as COSV56713979, COSV56714628; called by muse, mutect2, varscan2
- CUBN | c.7550G>C p.R2517T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.326); catalogued as COSV64719513; called by muse, mutect2, varscan2
- CYP4A22 | c.696G>C p.M232I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53740976; called by muse, mutect2, varscan2
- DCUN1D2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60261636; called by muse, mutect2, varscan2
- DNAH8 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV59458489; called by muse, mutect2, varscan2
- EFCAB5 | c.3102G>C p.E1034D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV100299717, COSV57932328; called by muse, mutect2, varscan2
- EGFR | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51814701; called by muse, mutect2, varscan2
- EIF2B5 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as COSV99889086; called by muse, mutect2, varscan2
- ELMO1 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs530807698, COSV60310290; called by muse, mutect2, varscan2
- EPB41L3 | c.641T>G p.V214G | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59458465; called by muse, mutect2, varscan2
- ETAA1 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs541916274, COSV55473832; called by muse, mutect2, varscan2
- FAM71B | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV57228097; called by muse, mutect2, varscan2
- FCRL4 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1430726032, COSV54863439; called by muse, mutect2, varscan2
- FERMT1 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99451293; called by muse, mutect2
- FLG2 | c.5779G>A p.G1927R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV66169809; called by muse, mutect2, varscan2
- FREM2 | c.1847A>C p.H616P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV54842231; called by muse, varscan2
- FZD7 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV53810127; called by muse, mutect2, varscan2
- GABRA5 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs1328857004, COSV59476783; called by muse, mutect2, varscan2
- GALNT2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV64195909; called by muse, varscan2
- GK | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV66737517; called by muse, mutect2, varscan2
- GNB4 | c.104C>G p.S35* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV99224133; called by muse, mutect2, varscan2
- GPR101 | c.384T>A p.D128E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99981317; called by muse, mutect2
- GRB14 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99813827; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV63100503; called by muse, mutect2, varscan2
- HECTD2 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.175); catalogued as COSV53222298; called by muse, mutect2, varscan2
- HECW1 | c.3674G>C p.R1225T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67832982, COSV67834742; called by muse, mutect2, varscan2
- HIVEP2 | c.4573G>C p.D1525H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.972); catalogued as COSV50020716; called by muse, mutect2, varscan2
- HLA-DPA1 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV101343099, COSV70089312; called by muse, mutect2
- HLA-DPA1 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70089324; called by muse, mutect2
- HMCN1 | c.4005G>C p.E1335D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV54912740; called by muse, mutect2, varscan2
- IDO1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768938457, COSV99503227; called by muse, varscan2
- IGF2R | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63630269; called by muse, mutect2, varscan2
- IGLON5 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765063492, COSV54536162; called by muse, mutect2, varscan2
- IREB2 | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51924131; called by muse, mutect2, varscan2
- ISG20L2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57460609; called by muse, mutect2, varscan2
- ITGAV | c.2523C>G p.I841M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53714676; called by muse, mutect2, varscan2
- KMT2E | c.5194C>T p.H1732Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV57575770; called by muse, mutect2, varscan2
- KRT78 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV58852220; called by muse, mutect2, varscan2
- LAMA3 | c.7677A>T p.K2559N (on ENST00000313654 / NM_198129.4; = p.K950N on NM_000227.6) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV99334217; called by muse, mutect2, varscan2
- LGR4 | c.830+2T>C p.X277_splice | Splice Site (SNP) | VAF 17/27 reads (63%) | catalogued as COSV64864907; called by muse, mutect2, varscan2
- LINS1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs967642441, COSV59079701, COSV59081056; called by muse, mutect2, varscan2
- LZTS3 | c.286T>A p.S96T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.191); catalogued as COSV61278259; called by muse, mutect2, varscan2
- MAGEB6B | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV69689734; called by muse, mutect2, varscan2
- MAN2B2 | c.2930G>C p.R977T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV53453279; called by muse, mutect2
- MBLAC1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99498794; called by muse, mutect2, varscan2
- MUC5AC | c.13688C>G p.S4563C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.08); catalogued as COSV64369764; called by muse, mutect2, varscan2
- MYH7B | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53421722; called by muse, mutect2, varscan2
- MYH9 | c.3391G>C p.E1131Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99338190, COSV99339520; called by muse, mutect2
- NAP1L1 | c.126G>C p.M42I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV53875174; called by muse, mutect2, varscan2
- NBEAL1 | c.4511C>G p.S1504* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101495623; called by muse, varscan2
- NBEAL1 | c.4595C>T p.S1532L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV71374749; called by muse, varscan2
- NCKAP1 | c.2712G>C p.L904F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV62941813; called by muse, mutect2, varscan2
- NFKBIZ | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58200931, COSV58200965; called by muse, mutect2, varscan2
- NTNG1 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53976849, COSV99636510; called by muse, mutect2, varscan2
- NWD1 | c.3116A>G p.H1039R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60344955; called by muse, mutect2, varscan2
- OBSL1 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs768202370, COSV54722904; called by muse, mutect2, varscan2
- OR10C1 | c.118G>A p.V40M (on ENST00000622521; = p.V38M on NM_013941.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs770812709, COSV65822372, COSV65823334; called by muse, mutect2, varscan2
- PAPPA2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV62780713; called by muse, mutect2, varscan2
- PCDHA2 | c.1976T>G p.L659W | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781820194, COSV65368228; called by muse, mutect2
- PCDHB16 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.125); catalogued as COSV53358451; called by muse, mutect2, varscan2
- PHF3 | c.4393C>G p.P1465A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV50318347, COSV50323598; called by muse, mutect2, varscan2
- PHIP | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51506446, COSV99243633; called by muse, mutect2, varscan2
- PHKB | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV100067493, COSV54525405; called by muse, varscan2
- PLCE1 | c.2965G>A p.V989M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs763441024, COSV53357248; called by muse, mutect2, varscan2
- POGLUT1 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV55157266; called by muse, mutect2, varscan2
- PPFIBP1 | c.1555C>T p.R519* (on ENST00000318304 / NM_177444.3; = p.R502* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs754653878, COSV57291371; called by muse, mutect2, varscan2
- PPIE | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV60972127; called by muse, mutect2, varscan2
- PTPRD | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs111386968; called by muse, mutect2, varscan2
- PTPRZ1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV66440116; called by muse, mutect2, varscan2
- SEC16A | c.6420G>C p.W2140C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99256877, COSV99259652; called by muse, mutect2, varscan2
- SEMG2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.885); catalogued as COSV65647325, COSV65647617; called by muse, mutect2, varscan2
- SI | c.3881T>C p.I1294T | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs752481222, COSV52285603; called by muse, mutect2, varscan2
- SI | c.2549C>T p.T850I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs1438057964, COSV100014551; called by muse, mutect2
- SIGLEC6 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs780557269, COSV58431654; called by muse, mutect2, varscan2
- SLC6A1 | c.1076C>G p.S359* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99822557; called by muse, mutect2
- SLTM | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51055219; called by muse, mutect2, varscan2
- SNAI1 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54864373; called by muse, mutect2, varscan2
- SND1 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as COSV61240369; called by muse, mutect2, varscan2
- SPEG | c.6431G>A p.R2144Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs768837753, COSV56663811; called by muse, varscan2
- SPTAN1 | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 38/49 reads (78%) | catalogued as COSV100823357; called by muse, mutect2, varscan2
- STAG2 | c.3441del p.E1147Dfs*16 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as COSV54357481; called by mutect2, pindel, varscan2
- SV2A | c.1724C>A p.T575K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV64965185; called by muse, mutect2, varscan2
- SVEP1 | c.5453G>T p.G1818V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52841807, COSV52845196; called by muse, mutect2
- SZT2 | c.3431C>T p.S1144L (on ENST00000634258 / NM_001365999.1; = p.S1087L on NM_015284.4) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65170170; called by muse, mutect2, varscan2
- TMEM106C | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV56742975; called by muse, varscan2
- TMPRSS11B | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV60291577, COSV60293004; called by muse, mutect2, varscan2
- TOP2A | c.3134C>A p.S1045Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.209); catalogued as COSV70732401, COSV70732921; called by muse, mutect2, varscan2
- TRA2B | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52024922; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs199665200; called by muse, varscan2
- TRAF3IP1 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100966969, COSV64853241; called by muse, varscan2
- TRAFD1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV57504971; called by muse, mutect2, varscan2
- TRAFD1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504981; called by muse, varscan2
- TRIO | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59990873; called by muse, mutect2, varscan2
- TRMT5 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV50783468; called by muse, mutect2, varscan2
- TRPA1 | c.1512dup p.G505Rfs*7 | Frame Shift Ins (INS) | VAF 8/71 reads (11%) | catalogued as rs770577826; called by mutect2, pindel, varscan2
- TRPV2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV58429071; called by muse, mutect2, varscan2
- TRUB1 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100076024; called by muse, mutect2
- TSPAN8 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs751276179, COSV56079106; called by muse, mutect2, varscan2
- TTN | c.5258T>C p.M1753T (on ENST00000591111; = p.M1707T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | PolyPhen benign (0.295); catalogued as COSV60154008; called by muse, mutect2, varscan2
- UBE3A | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV51667449; called by muse, mutect2, varscan2
- UTRN | c.6443C>T p.S2148L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62339490; called by muse, mutect2, varscan2
- VCAM1 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54120268; called by muse, mutect2, varscan2
- WIPF1 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55815523, COSV55816400; called by muse, mutect2, varscan2
- WNT16 | c.262G>T p.E88* (on ENST00000222462 / NM_057168.2; = p.E78* on NM_016087.2) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs749225268, COSV55975691, COSV99742885, COSV99743006; called by muse, mutect2, varscan2
- XIRP2 | c.2803G>C p.V935L (on ENST00000628543; = p.V1110L on NM_152381.6) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs780738911, COSV54711506; called by muse, mutect2, varscan2
- ZC3H7A | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV63270134; called by muse, varscan2
- ZHX2 | c.1946G>C p.R649T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58714404; called by muse, mutect2, varscan2
- ZNF132 | c.1404C>G p.F468L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54235273; called by muse, mutect2, varscan2
- ZNF208 | c.2150G>C p.G717A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV68101556, COSV68108787; called by muse, varscan2
- ZNF502 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as COSV56074023; called by muse, mutect2, varscan2
- ZNF667 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52636115, COSV99410981; called by muse, mutect2, varscan2
- ZNF804B | c.2603G>C p.S868T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100304533, COSV60835168; called by muse, mutect2, varscan2
- ZNF827 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV65228841; called by muse, mutect2, varscan2
- IZUMO1R | c.403G>A p.D135N (on ENST00000440961; = p.D142N on NM_001199206.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- TAOK2 | c.2712_2714del p.E907del | In Frame Del (DEL) | VAF 18/75 reads (24%) | called by pindel, varscan2
- TRAV23DV6 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ABI3 | c.306G>A p.E102= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56800619; called by muse, mutect2, varscan2
- ACACA | c.2319C>T p.I773= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- ADGRL4 | c.1677C>G p.T559= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV66062525; called by muse, mutect2, varscan2
- ALDH3A1 | c.9G>A p.K3= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV56735810; called by muse, mutect2, varscan2
- ANGPTL4 | c.1125G>A p.K375= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV56845040; called by muse, mutect2, varscan2
- C19orf18 | c.498G>A p.E166= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV58706500; called by muse, mutect2, varscan2
- C21orf62 | c.525C>T p.F175= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV66672260; called by muse, mutect2, varscan2
- CAND1 | c.3060G>A p.L1020= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1488363828, COSV73389673; called by muse, mutect2, varscan2
- CBWD1 | c.114C>T p.L38= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs779418945, COSV100070719; called by muse, mutect2, varscan2
- CD180 | c.681G>A p.L227= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs1192077978, COSV56518622; called by muse, mutect2, varscan2
- CHD2 | c.3444C>G p.L1148= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV67711017, COSV67712136; called by muse, mutect2, varscan2
- CYP2S1 | c.1344G>A p.A448= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs763569535, COSV59506303; called by muse, varscan2
- DNAH17 | c.6360C>T p.V2120= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1471445044, COSV67757302; called by muse, mutect2
- DNAH8 | c.3318G>A p.L1106= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59458461, COSV59486784; called by muse, mutect2, varscan2
- FAAH | c.1332C>G p.L444= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV54544652; called by muse, mutect2, varscan2
- FAM71A | c.1392C>T p.F464= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV54236176; called by muse, mutect2, varscan2
- FAM91A1 | c.1420C>T p.L474= | Silent (SNP) | VAF 116/263 reads (44%) | catalogued as COSV58237861; called by muse, mutect2, varscan2
- FGF2 | c.753G>A p.R251= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52650903; called by muse, mutect2, varscan2
- HNRNPA0 | c.168C>G p.S56= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59246704; called by muse, mutect2, varscan2
- IBTK | c.537C>T p.I179= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs773049124, COSV60393948; called by muse, mutect2, varscan2
- KCNF1 | c.393G>A p.L131= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54464202; called by muse, mutect2, varscan2
- KCTD3 | c.2265G>A p.K755= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV52068059; called by muse, mutect2, varscan2
- KLHL31 | c.270C>G p.V90= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV63882007; called by muse, mutect2, varscan2
- KRT73 | c.1059G>T p.L353= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59839984; called by muse, mutect2, varscan2
- L3MBTL2 | c.66C>T p.D22= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs201966770; called by muse, mutect2, varscan2
- LGALS14 | c.111G>A p.E37= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV62372866; called by muse, mutect2, varscan2
- LIPE | c.1266C>G p.L422= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54923789; called by muse, mutect2, varscan2
- MDN1 | c.10032G>A p.Q3344= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65523996; called by muse, mutect2, varscan2
- NEIL3 | c.186G>A p.Q62= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV52811547; called by muse, mutect2, varscan2
- PCNX3 | c.3783C>T p.H1261= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs772246478, COSV63137667; called by muse, mutect2, varscan2
- RIN3 | c.1809G>A p.K603= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV53651101; called by muse, mutect2, varscan2
- RNF216 | c.1857G>A p.K619= (on ENST00000425013 / NM_207116.3; = p.K676= on NM_207111.4) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV66290439, COSV66291323; called by muse, mutect2, varscan2
- RNLS | c.60G>A p.L20= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV59295826; called by muse, mutect2, varscan2
- SCNN1G | c.165C>T p.L55= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV55599763; called by muse, mutect2, varscan2
- SERPINA12 | c.1179G>A p.L393= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV57944503; called by muse, mutect2, varscan2
- SLC18A3 | c.693C>T p.F231= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1407074812, COSV60327506; called by muse, mutect2
- SPIRE2 | c.1800C>T p.S600= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV65556490; called by muse, mutect2, varscan2
- TTLL1 | c.1122C>T p.V374= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs560814513, COSV56739270; called by muse, varscan2
- TTLL1 | c.1029C>G p.L343= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs974493407, COSV56739282; called by muse, varscan2
- UBD | c.219C>A p.T73= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV63542279; called by muse, mutect2, varscan2
- ZNF786 | c.1578G>A p.E526= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1239496348, COSV60276829; called by muse, mutect2, varscan2
- PIP4K2A | c.678+134C>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs989824523, COSV100114412; called by muse, mutect2
